Gene-level copy-number profile of tumor specimen ALCH-B4EY-TTP1-A from ALCHEMIST case ALCH-B4EY, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: female; Primary diagnosis: Squamous cell carcinoma, NOS; Age at diagnosis: 62.7 years (22,911 days).
Specimen ALCH-B4EY-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 79937ec0-1c6a-4b7c-bba3-c86d621bb41f.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator ALCH-B4EY-NB1-A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,239 have no estimate.
https://portal.gdc.cancer.gov/files/ee21f154-1eec-4816-96f2-d9fcd4ec780f

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 18; copy number 1: 1,701; copy number 2: 51,472; copy number 3: 4,717; copy number 4: 390; copy number 5: 54; copy number 6: 12; copy number 7: 4; copy number 10: 8; copy number 12: 4; copy number 17: 1; copy number 19: 1; copy number 25: 1; copy number 33: 1.

Homozygous deletions (total copy number 0; autosomes only): 8 genes in 8 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:196,774,813–196,795,407, 1 gene: CFHR3.
- chr2:131,328,176–131,330,857, 1 gene (within-gene range 0–2): ARHGAP42P1.
- chr6:32,005,636–32,008,451, 1 gene: CYP21A1P.
- chr7:227,554–229,557, 1 gene (within-gene range 0–1): AC145676.1.
- chr15:61,181,249–61,195,938, 1 gene (within-gene range 0–2): AC012404.1.
- chr16:2,047,967–2,089,491, 1 gene (within-gene range 0–2): TSC2.
- chr19:19,320,829–19,358,754, 1 gene (within-gene range 0–3): MAU2.
- chr20:62,387,103–62,388,520, 1 gene: RPS21.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 82 genes in 19 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr3:128,714,571–128,714,705, 1 gene, copy number 5: AC079945.1.
- chr3:165,772,904–166,570,763, 8 genes, copy number 5: BCHE, MTND4P17, MTND4LP10, MTND3P7, MTCO3P38, MCUR1P2, AC104629.1, LINC01326.
- chr3:172,039,578–172,401,669, 4 genes, copy number 6: FNDC3B, RPS27AP8, RN7SL141P, AC092964.1.
- chr4:25,861,830–26,490,484, 5 genes, copy number 12–25 (within-gene range 2–25): SMIM20, AC133961.1, AC097714.1, RBPJ, CCKAR.
- chr11:32,583,798–33,357,023, 18 genes, copy number 5 (within-gene range 3–5): EIF3M, HNRNPA3P9, CCDC73, AL049714.1, PRRG4, QSER1, Y_RNA, DEPDC7, TCP11L1, PIGCP1, LINC00294, CSTF3, CSTF3-DT, Y_RNA, RPL29P23, Y_RNA, AL136126.1, HIPK3.
- chr14:103,847,721–103,880,381, 3 genes, copy number 5 (within-gene range 5–6): LINC00637, AL132712.1, AL132712.2.
- chr14:104,857,792–104,858,836, 1 gene, copy number 5: AL583810.1.
- chr15:21,951,242–21,981,245, 2 genes, copy number 6–7: MIR5701-3, OR11J6P.
- chr15:28,506,625–28,579,400, 6 genes, copy number 6–12: ABCB10P4, GOLGA8G, Metazoa_SRP, AC138749.3, AC138749.1, HERC2P11.
- chr16:32,600,299–32,615,639, 1 gene, copy number 5: AC137800.1.
- chr16:32,649,193–32,788,944, 13 genes, copy number 5–10: AC138907.7, AC138907.5, AC138907.1, TP53TG3, AC138907.3, AC138907.6, ABHD17AP7, AC138907.2, AC138907.4, HERC2P5, AC138907.8, AC138907.9, AC138907.10.
- chr17:40,177,010–40,284,136, 3 genes, copy number 5: RAPGEFL1, MIR6867, WIPF2.
- chr19:397,589–399,173, 1 gene, copy number 7: AC010641.1.
- chr19:825,097–832,018, 1 gene, copy number 5: AZU1.
- chr19:55,352,301–55,384,292, 6 genes, copy number 5 (within-gene range 2–5): AC020922.1, FAM71E2, IL11, TMEM190, AC020922.3, TMEM238.
- chr22:21,114,607–21,124,451, 1 gene, copy number 19 (within-gene range 2–19): AP000550.1.
- chr22:21,167,758–21,203,755, 3 genes, copy number 5 (within-gene range 5–9): FAM230B, AP000550.2, FAM247A.
- chr22:21,228,760–21,284,161, 3 genes, copy number 5: AP000550.3, E2F6P3, POM121L8P.
- chr22:21,341,595–21,358,067, 2 genes, copy number 5–33: PPP1R26P5, LINC01651.

Autosomal genes at a single copy (total copy number 1): 1,699. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
